Somatic mutation profile of cancer-model specimen HCM-CSHL-0078-C25-85Q (3D Organoid, passage 14; aliquot HCM-CSHL-0078-C25-85Q-01D-A85K-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85Q: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad43ef17-1e4d-4131-8cc8-906019c99f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0078-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0078-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec577d44-ae1c-4475-8a4c-ec9ebd40a934

The open-access MAF lists 105 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Nonsense Mutation 6, Intron 4, Frame Shift Del 4, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 385/385 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.3062G>C p.G1021A | Missense Mutation (SNP) | VAF 170/365 reads (47%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1237911024; called by muse, mutect2, varscan2
- ANKRD34C | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 139/572 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as rs1242375934; called by muse, mutect2, varscan2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CDC5L | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 271/413 reads (66%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs756396867; called by muse, mutect2, varscan2
- CDH18 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 174/265 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56926703; called by muse, mutect2, varscan2
- CTNND2 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 221/361 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs367931998, COSV58893133; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 161/163 reads (99%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- GDF7 | c.125_126insTGGCGGCGG p.G48_G50dup | In Frame Ins (INS) | VAF 254/441 reads (58%) | catalogued as rs1553327113; called by mutect2, varscan2*
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 298/775 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- KLF12 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 185/292 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs774840041; called by muse, mutect2, varscan2
- LPA | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 133/223 reads (60%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1170862921, COSV60303792; called by muse, mutect2, varscan2
- MECR | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs749351701; called by muse, mutect2, varscan2
- NIPBL | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.511); catalogued as rs372266009; called by muse, mutect2, varscan2
- NPIPB11 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 248/331 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.876); catalogued as rs796341971; called by muse, varscan2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 126/674 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by mutect2, varscan2
- OR5A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 240/415 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs796662079, COSV57378244; called by muse, mutect2
- OR5D13 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 221/369 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs750305125, COSV62334227; called by muse, mutect2, varscan2
- PALM | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 266/444 reads (60%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372771354; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 167/684 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- PRB1 | c.453+2G>A | Missense Mutation (SNP) | VAF 118/208 reads (57%) | catalogued as rs199764037, COSV53702943; called by muse, varscan2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- SLC38A8 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 132/402 reads (33%) | catalogued as COSV55309170; called by muse, mutect2, varscan2
- SPN | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs968049985, COSV64070098; called by muse, mutect2, varscan2
- TAOK2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 316/501 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs746118559, COSV54234689; called by muse, mutect2, varscan2
- TBC1D9B | c.3517G>A p.D1173N (on ENST00000356834 / NM_198868.3; = p.D1156N on NM_015043.4) | Missense Mutation (SNP) | VAF 303/459 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs749545069, COSV52975404; called by muse, mutect2, varscan2
- THAP12 | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs9666739; called by muse, mutect2
- TMEM91 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 234/362 reads (65%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as rs1032654429, COSV99652565; called by muse, mutect2, varscan2
- TRPM5 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 117/370 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs759723253, COSV50214474; called by muse, mutect2, varscan2
- UACA | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 210/280 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778220594; called by muse, mutect2, varscan2
- UNC13A | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1343787229, COSV53193297; called by muse, mutect2, varscan2
- VEPH1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 181/257 reads (70%) | catalogued as COSV62882192; called by muse, mutect2, varscan2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 185/537 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- ACVR1B | c.552C>G p.Y184* | Nonsense Mutation (SNP) | VAF 83/239 reads (35%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4396A>G p.S1466G (on ENST00000506720 / NM_001322402.2; = p.S1355G on NM_015236.6) | Missense Mutation (SNP) | VAF 133/284 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AMBRA1 | c.3115G>T p.E1039* (on ENST00000458649 / NM_001367468.1; = p.E949* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 130/211 reads (62%) | called by muse, mutect2, varscan2
- ANO7 | c.524C>T p.S175F (on ENST00000274979; = p.S121F on NM_001370694.2) | Missense Mutation (SNP) | VAF 260/639 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ARFGEF3 | c.2435G>C p.S812T | Missense Mutation (SNP) | VAF 193/299 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP35 | c.80A>G p.E27G | Missense Mutation (SNP) | VAF 147/416 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BIRC6 | c.9946T>C p.F3316L | Missense Mutation (SNP) | VAF 170/322 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CACFD1 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH23 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 209/330 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CHI3L2 | c.741T>A p.Y247* | Nonsense Mutation (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- COG3 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DDX31 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 199/309 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.8009C>A p.A2670E | Missense Mutation (SNP) | VAF 239/509 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DNASE2 | c.141_142del p.G48Afs*49 | Frame Shift Del (DEL) | VAF 246/561 reads (44%) | called by pindel, varscan2
- EPHA5 | c.2927C>A p.A976E | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FAM169A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 178/311 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FOXC1 | c.18dup p.V7Rfs*76 | Frame Shift Ins (INS) | VAF 134/188 reads (71%) | called by mutect2, pindel, varscan2
- GOLGA8K | c.738A>T p.K246N | Missense Mutation (SNP) | VAF 94/469 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- INTS3 | c.1824A>C p.E608D | Missense Mutation (SNP) | VAF 56/559 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- KDM5C | c.1503_1519del p.W501Cfs*10 | Frame Shift Del (DEL) | VAF 175/186 reads (94%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 204/320 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAP3K6 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- MED14 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MUC6 | c.6589_6590del p.L2197Ffs*12 | Frame Shift Del (DEL) | VAF 352/782 reads (45%) | called by pindel, varscan2
- NEB | c.16955A>G p.Y5652C | Missense Mutation (SNP) | VAF 309/313 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7E24 | c.1007G>C p.C336S | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE6B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PTPN13 | c.7224C>A p.C2408* (on ENST00000411767 / NM_080683.3; = p.C2389* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 115/235 reads (49%) | called by muse, mutect2, varscan2
- RBM23 | c.1309C>A p.Q437K (on ENST00000359890 / NM_001077351.2; = p.Q421K on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/372 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- RBM26 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RFPL3 | c.200T>C p.L67P (on ENST00000249007 / NM_001098535.1; = p.L38P on NM_006604.2) | Missense Mutation (SNP) | VAF 312/332 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIOK2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SAMD8 | c.204A>T p.L68F | Missense Mutation (SNP) | VAF 188/313 reads (60%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC26A3 | c.1927A>C p.K643Q | Missense Mutation (SNP) | VAF 131/475 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SLC5A8 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 126/214 reads (59%) | called by pindel, varscan2
- TANC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 454/457 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TAS2R40 | c.913del p.R305Efs*14 | Frame Shift Del (DEL) | VAF 78/425 reads (18%) | called by mutect2, pindel, varscan2
- THSD4 | c.1534-1G>A p.X512_splice | Splice Site (SNP) | VAF 72/297 reads (24%) | called by muse, mutect2, varscan2
- TNKS | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 459/707 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WNK2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 154/664 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX2 | c.6059G>C p.S2020T | Missense Mutation (SNP) | VAF 321/484 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZGRF1 | c.4748T>G p.I1583S | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF202 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1377C>T p.P459= | Silent (SNP) | VAF 282/715 reads (39%) | catalogued as rs779949072, COSV55000365; called by muse, mutect2, varscan2
- AGPAT3 | c.462C>T p.T154= | Silent (SNP) | VAF 233/236 reads (99%) | catalogued as rs143039422; called by muse, mutect2, varscan2
- AVPR1A | c.117C>T p.N39= | Silent (SNP) | VAF 159/448 reads (35%) | called by muse, mutect2, varscan2
- C1QL1 | c.159C>T p.S53= | Silent (SNP) | VAF 361/564 reads (64%) | called by muse, mutect2, varscan2
- CLSTN2 | c.696G>T p.L232= | Silent (SNP) | VAF 227/359 reads (63%) | called by muse, mutect2, varscan2
- DNAH7 | c.9168T>C p.F3056= | Silent (SNP) | VAF 205/427 reads (48%) | called by muse, mutect2, varscan2
- DPF2 | c.432C>T p.G144= | Silent (SNP) | VAF 208/302 reads (69%) | catalogued as COSV52888870; called by muse, mutect2, varscan2
- EVC2 | c.3615C>T p.S1205= | Silent (SNP) | VAF 78/178 reads (44%) | called by muse, mutect2, varscan2
- FLG | c.7242C>T p.F2414= | Silent (SNP) | VAF 417/768 reads (54%) | called by muse, mutect2, varscan2
- GALNT9 | c.867C>T p.N289= | Silent (SNP) | VAF 164/478 reads (34%) | catalogued as rs554022886, COSV61095893; called by muse, mutect2, varscan2
- GNA11 | c.192C>T p.G64= | Silent (SNP) | VAF 289/438 reads (66%) | catalogued as rs755663461; called by muse, mutect2, varscan2
- GSG1 | c.240A>G p.G80= (on ENST00000651961 / NM_001080555.4; = p.G67= on NM_031289.5) | Silent (SNP) | VAF 114/542 reads (21%) | called by muse, mutect2, varscan2
- HTR3A | c.1362C>T p.F454= | Silent (SNP) | VAF 136/430 reads (32%) | called by muse, mutect2, varscan2
- IRX3 | c.1473C>T p.A491= | Silent (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- KLHL15 | c.969T>C p.A323= | Silent (SNP) | VAF 304/311 reads (98%) | catalogued as rs1569264183, COSV60141503; called by muse, mutect2, varscan2
- NEXMIF | c.1749C>T p.P583= | Silent (SNP) | VAF 267/269 reads (99%) | called by muse, mutect2, varscan2
- PSMB11 | c.498C>T p.D166= | Silent (SNP) | VAF 345/538 reads (64%) | catalogued as rs375580593; called by muse, mutect2, varscan2
- RFPL3 | c.201G>T p.L67= (on ENST00000249007 / NM_001098535.1; = p.L38= on NM_006604.2) | Silent (SNP) | VAF 313/333 reads (94%) | called by muse, mutect2, varscan2
- RXRB | c.966T>A p.P322= | Silent (SNP) | VAF 295/2466 reads (12%) | called by muse, mutect2, varscan2
- SLC34A1 | c.966C>T p.A322= | Silent (SNP) | VAF 207/320 reads (65%) | called by muse, mutect2, varscan2
- TIE1 | c.2826T>C p.A942= | Silent (SNP) | VAF 270/420 reads (64%) | called by muse, mutect2, varscan2
- TSPAN5 | c.606T>C p.Y202= | Silent (SNP) | VAF 94/208 reads (45%) | catalogued as rs760214816; called by muse, mutect2, varscan2
- VN1R2 | c.198T>G p.L66= | Silent (SNP) | VAF 98/384 reads (26%) | called by muse, mutect2, varscan2
- GPNMB | c.541+30C>A | Intron (SNP) | VAF 259/540 reads (48%) | called by muse, mutect2, varscan2
- IL5RA | c.994+1973T>C | Intron (SNP) | VAF 174/268 reads (65%) | catalogued as COSV99843239; called by muse, mutect2, varscan2
- PADI4 | c.-2C>T | 5'UTR (SNP) | VAF 168/253 reads (66%) | catalogued as rs200461292; called by muse, mutect2, varscan2
- PIBF1 | c.2049+46dup | Intron (INS) | VAF 151/340 reads (44%) | called by mutect2, pindel, varscan2
- PYCARD | c.275-76del | Intron (DEL) | VAF 107/212 reads (50%) | called by mutect2, pindel, varscan2
